Somatic mutation profile of tumor specimen HTMCP-03-06-02111-01A (aliquot HTMCP-03-06-02111-01A-01D-5099) from CGCI case HTMCP-03-06-02111, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.8 years (18,190 days).
Specimen HTMCP-03-06-02111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d963b0bd-071e-4708-979a-12caea7146c7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02111-10A (Blood Derived Normal), aliquot HTMCP-03-06-02111-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/190c13c0-65f9-4154-ae2a-a5928305a8b5

The open-access MAF lists 73 somatic variants for this specimen: 47 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 22, Nonsense Mutation 5, Intron 2, Splice Site 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- ADRA1A | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as rs140512348, COSV99372231; called by muse, mutect2, varscan2
- CDH10 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100050252; called by muse, mutect2, varscan2
- GFPT2 | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53810894; called by muse, mutect2
- JPH1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs142421841; called by muse, mutect2, varscan2
- KCNMA1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1465957812; called by muse, mutect2, varscan2
- KDM6A | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 15/174 reads (9%) | catalogued as COSV65041976; called by muse, mutect2
- LARGE1 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs368030516; called by muse, mutect2, varscan2
- LRP12 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs577413361, COSV52627002; called by muse, mutect2, varscan2
- MYH11 | c.3340C>T p.R1114W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202004234, COSV100259005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 59/152 reads (39%) | catalogued as COSV55563405; called by muse, mutect2, varscan2
- NFASC | c.2446G>A p.V816I (on ENST00000339876 / NM_001378329.1; = p.V812I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as rs201163175; called by muse, mutect2, varscan2
- NWD2 | c.4754G>C p.R1585P | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.095); catalogued as COSV58748007; called by muse, mutect2, varscan2
- OR2W1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs745574396, COSV65851508; called by muse, mutect2, varscan2
- OR4C13 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.028); catalogued as rs1484574368; called by muse, mutect2, varscan2
- PAPSS2 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs774132241, COSV63262650; called by muse, mutect2, varscan2
- PDS5A | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs868220045, COSV100337332; called by muse, mutect2, varscan2
- PLXNA3 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs782448475, COSV63755828; called by muse, mutect2, varscan2
- PPP1R10 | c.461-8C>G | Splice Region (SNP) | VAF 19/51 reads (37%) | catalogued as rs1399230651; called by muse, mutect2, varscan2
- PTPRB | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV54249617; called by muse, mutect2
- SNTG2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as rs201970591; called by muse, mutect2, varscan2
- TEX11 | c.358C>T p.R120* (on ENST00000344304; = p.R105* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 86/188 reads (46%) | catalogued as rs1486675411, COSV60228091, COSV60228924; called by muse, mutect2, varscan2
- TTLL5 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54034361; called by muse, mutect2, varscan2
- ZFYVE26 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs573210032, COSV61329780; called by muse, mutect2, varscan2
- ZNF304 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1219439508; called by muse, mutect2, varscan2
- ABCC8 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CATSPERD | c.1369-20_1371del p.X457_splice | Splice Site (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel
- CCDC14 | c.2647G>C p.D883H (on ENST00000488653; = p.D835H on NM_022757.5) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAN1 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- FOLH1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FREM3 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 79/110 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KAT6A | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LAMA3 | c.5450A>T p.E1817V (on ENST00000313654 / NM_198129.4; = p.E208V on NM_000227.6) | Missense Mutation (SNP) | VAF 117/214 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- LRRTM3 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- LY75-CD302 | c.5081G>C p.R1694T | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTHFD1 | c.2689G>T p.A897S | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- NOP14 | c.2474+1G>A p.X825_splice | Splice Site (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 130/354 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PIK3C2B | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PTPRM | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QSER1 | c.3051G>C p.E1017D (on ENST00000399302; = p.E1146D on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- RARG | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNFT2 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 27/27 reads (100%) | called by muse, mutect2, varscan2
- RYR2 | c.13357G>T p.A4453S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- STYXL2 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TMEM132D | c.2861A>G p.E954G | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHR | c.953T>G p.L318W | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- ABCA13 | c.7536G>C p.L2512= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as rs770142245; called by muse, mutect2, varscan2
- AHI1 | c.2538G>A p.K846= | Silent (SNP) | VAF 110/268 reads (41%) | called by muse, mutect2, varscan2
- CD226 | c.603C>T p.H201= | Silent (SNP) | VAF 127/198 reads (64%) | catalogued as rs770109810; called by muse, mutect2, varscan2
- DYNC2H1 | c.5247T>C p.S1749= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- FLT1 | c.2646G>A p.L882= | Silent (SNP) | VAF 32/36 reads (89%) | called by muse, mutect2, varscan2
- GRM3 | c.1152C>T p.Y384= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as rs766987217, COSV64473635; called by muse, mutect2, varscan2
- IGF1R | c.1116A>G p.S372= | Silent (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- KALRN | c.2742C>T p.N914= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs997627875, COSV99564838; called by muse, mutect2, varscan2
- KIAA1210 | c.2817C>T p.S939= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as rs766310249, COSV101274326, COSV68176668; called by muse, mutect2, varscan2
- LRP1B | c.5182C>T p.L1728= | Silent (SNP) | VAF 49/106 reads (46%) | called by muse, mutect2, varscan2
- MICAL3 | c.702G>T p.R234= | Silent (SNP) | VAF 78/140 reads (56%) | called by muse, mutect2, varscan2
- NEMF | c.1905C>T p.F635= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs778294061; called by mutect2, varscan2
- NLRP11 | c.951G>A p.Q317= | Silent (SNP) | VAF 71/172 reads (41%) | catalogued as rs374485846; called by muse, mutect2, varscan2
- NUP153 | c.3274C>T p.L1092= | Silent (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- PCDH11X | c.66C>T p.G22= | Silent (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- PCSK5 | c.2658G>A p.Q886= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs895027308; called by muse, mutect2, varscan2
- RBFOX1 | c.234G>A p.A78= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs1490574094, COSV60959172; called by muse, mutect2, varscan2
- TRIM46 | c.2265C>T p.F755= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs746702791, COSV100104019; called by muse, varscan2
- TRIO | c.4944G>A p.T1648= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs112809301; called by muse, mutect2, varscan2
- ZFYVE9 | c.747C>T p.D249= | Silent (SNP) | VAF 62/224 reads (28%) | catalogued as rs199918282, COSV99819277; called by muse, mutect2, varscan2
- ZNF536 | c.600C>T p.H200= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100834500; called by muse, mutect2, varscan2
- ZNF775 | c.1068G>A p.L356= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- AC011467.6 | chr19:22514371 G>T | 5'Flank (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- GRM1 | c.2661-7248C>G | Intron (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- NRXN1 | c.4039-30228G>A | Intron (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- RBM6 | c.*1G>A | 3'UTR (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
